Gene-level copy-number profile of tumor specimen AP-XCJX-9C from APOLLO case AP-XCJX, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2.
Specimen AP-XCJX-9C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a6206c8e-2ba6-4fc0-a7d5-d08460121b42.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-XCJX-YR (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/52edcc91-6a2d-4d69-a96a-e97af0cf204e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,856; copy number 2: 54,088; copy number 3: 1,934; copy number 4: 37.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
